Somatic mutation profile of tumor specimen TCGA-LN-A49W-01A (aliquot TCGA-LN-A49W-01A-11D-A27G-09) from TCGA case TCGA-LN-A49W, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 73.7 years (26,910 days).
Specimen TCGA-LN-A49W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b29092f-d1df-430a-a90d-843cb138e7b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A49W-10A (Blood Derived Normal), aliquot TCGA-LN-A49W-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdb33164-eed6-444e-bc21-a23b38bb46f8

The open-access MAF lists 86 somatic variants for this specimen: 63 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 22, Frame Shift Ins 4, Splice Site 3, Nonsense Mutation 2, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN3 | c.2288A>G p.Y763C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs764459544, CD1514319, CM994482; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 99/280 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2023C>A p.P675T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.619); catalogued as COSV70027116; called by muse, mutect2, varscan2
- ANKFN1 | c.706G>C p.G236R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.383); catalogued as COSV59447589; called by muse, mutect2, varscan2
- ARAF | c.499C>A p.Q167K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs761480447; called by muse, mutect2, varscan2
- C11orf24 | c.460A>G p.M154V | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs754691280; called by muse, mutect2, varscan2
- C5orf24 | c.274C>T p.R92W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755244010, COSV57542764; called by mutect2, varscan2
- CABIN1 | c.3373G>A p.V1125I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs148592192; called by mutect2, varscan2
- CCDC6 | c.1269C>G p.F423L | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV54055808; called by muse, mutect2
- CNTNAP5 | c.657C>A p.F219L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV101443772, COSV70502003; called by muse, mutect2, varscan2
- CXXC4 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1233329382; called by muse, mutect2
- EGFR | c.3415C>T p.L1139F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1473630143, COSV51841863; called by muse, mutect2, varscan2
- FMN2 | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); catalogued as rs753347899; called by muse, varscan2
- HDAC4 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); catalogued as rs202206567; called by muse, mutect2
- IPO11 | c.2062A>G p.I688V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs776372328, COSV57572622; called by muse, mutect2, varscan2
- ITGB6 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs946554296; called by muse, mutect2, varscan2
- KIAA1210 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV68176004; called by muse, mutect2, varscan2
- LRRC6 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV51545755; called by muse, mutect2, varscan2
- MTUS1 | c.2893C>T p.R965W (on ENST00000262102 / NM_001363061.1; = p.R131W on NM_020749.4) | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs924802638, COSV99870709; called by muse, mutect2
- MYCN | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.36); catalogued as rs140581169; called by muse, mutect2, varscan2
- NLGN1 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.91); catalogued as COSV64327001; called by muse, mutect2, varscan2
- NOP58 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV51897652; called by muse, mutect2, varscan2
- NUAK1 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.287); catalogued as rs117517173; called by muse, mutect2, varscan2
- OR4K13 | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs998479002, COSV100237682; called by muse, mutect2, varscan2
- OSBPL9 | c.2042T>C p.I681T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs778762175; called by muse, mutect2, varscan2
- PCDH10 | c.2524C>A p.P842T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV99993596; called by muse, mutect2, varscan2
- PCDHB11 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.342); catalogued as COSV61310144; called by muse, mutect2, varscan2
- PDE1B | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.079); catalogued as rs1350794251; called by muse, mutect2, varscan2
- PITRM1 | c.1529A>G p.Y510C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564413979; called by muse, mutect2, varscan2
- PLAGL2 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs768542815, COSV55790015; called by muse, mutect2, varscan2
- SAFB | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV52650979; called by muse, mutect2, varscan2
- SLF1 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54367915, COSV54373593; called by muse, mutect2, varscan2
- TTN | c.30934A>G p.I10312V (on ENST00000591111; = p.I9385V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | PolyPhen benign (0); catalogued as rs753824961; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF280B | c.1564G>C p.V522L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.22); catalogued as rs144549774; called by mutect2, varscan2
- AC013489.1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAP2 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- BMPR1B | c.1183T>G p.Y395D | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C16orf71 | c.834dup p.E279Rfs*17 | Frame Shift Ins (INS) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- CDH11 | c.2384A>G p.D795G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- CFAP54 | c.5325-1G>C p.X1775_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- DPYD | c.2622+2T>G p.X874_splice | Splice Site (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- F5 | c.5479A>G p.R1827G | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- FBXL4 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FNIP1 | c.1690A>G p.M564V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- H4-16 | c.175dup p.L59Pfs*11 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- LGI2 | c.630C>A p.S210R | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- LSM14A | c.1089dup p.D364* | Frame Shift Ins (INS) | VAF 5/45 reads (11%) | called by mutect2, pindel, varscan2
- METTL4 | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- MIA2 | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.848); called by muse, varscan2
- MPPE1 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NOTCH2 | c.875-2A>T p.X292_splice | Splice Site (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2
- PCK2 | c.1374G>T p.G458= | Splice Region (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- PHLDB2 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR2C | c.606dup p.W203Mfs*5 | Frame Shift Ins (INS) | VAF 24/95 reads (25%) | called by mutect2, pindel, varscan2
- PRELP | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRF | c.2071G>C p.G691R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RBBP4 | c.985A>T p.N329Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RGS12 | c.2437C>A p.L813I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SMC5 | c.2815A>G p.I939V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- SPPL2B | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLL1 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ZBED9 | c.563A>T p.D188V | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- ZNF570 | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS18 | c.672T>C p.Y224= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- AGBL5 | c.1608G>A p.G536= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- ARMC8 | c.1546C>T p.L516= (on ENST00000469044 / NM_001363941.2; = p.L502= on NM_015396.6) | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100509911; called by muse, mutect2, varscan2
- ASTE1 | c.2016T>C p.H672= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV53910112; called by muse, mutect2
- CNTN2 | c.3090G>T p.A1030= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV59352094; called by muse, mutect2, varscan2
- DPY19L4 | c.510A>G p.G170= | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- HERC4 | c.21A>T p.A7= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- HRNR | c.6987C>T p.G2329= | Silent (SNP) | VAF 21/144 reads (15%) | called by muse, mutect2, varscan2
- ICAM5 | c.1452G>A p.T484= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs773640360; called by muse, mutect2, varscan2
- ILRUN | c.564G>A p.T188= (on ENST00000374023 / NM_024294.4; = p.T122= on NM_022758.6) | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- KCNB2 | c.1998G>A p.T666= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs1277870040, COSV73050439, COSV73051069; called by muse, mutect2, varscan2
- KCNH1 | c.1302G>C p.G434= (on ENST00000271751 / NM_172362.3; = p.G407= on NM_002238.4) | Silent (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- LCMT2 | c.138G>T p.A46= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as rs1198024578; called by muse, mutect2
- LCT | c.3348G>A p.Q1116= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- LMF2 | c.543C>A p.A181= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- NCOA6 | c.3855A>G p.Q1285= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs769062649; called by muse, mutect2, varscan2
- PCDH19 | c.606G>A p.S202= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs761463596, COSV55267053; called by muse, mutect2, varscan2
- PCIF1 | c.1146C>T p.I382= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- PRKD3 | c.645A>G p.V215= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs760047457; called by muse, mutect2, varscan2
- RPH3A | c.2073G>A p.V691= (on ENST00000389385 / NM_001143854.2; = p.V687= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV66990271; called by muse, mutect2, varscan2
- ST8SIA4 | c.291G>A p.V97= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs1353169143, COSV99185365; called by muse, mutect2, varscan2
- ZEB2 | c.384C>T p.T128= | Silent (SNP) | VAF 33/124 reads (27%) | catalogued as rs573552493, COSV57956241, COSV57956256; ClinVar: likely benign; called by muse, mutect2, varscan2
- HERC2P3 | n.1488A>G | RNA (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
